Somatic mutation profile of tumor specimen MMRF_2539_1_BM_CD138pos (aliquot MMRF_2539_1_BM_CD138pos_T1_KHS5U_K15141) from MMRF case MMRF_2539, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: female; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 51.8 years (18,918 days).
Specimen MMRF_2539_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 05b37fa3-ff2c-4ae8-ada2-6986a5f9f6cd.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_2539_1_PB_Whole (Blood Derived Normal), aliquot MMRF_2539_1_PB_Whole_C3_KHS5U_K15140; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ccd0ca1e-7e98-41af-8828-bd150dc47087

The open-access MAF lists 81 somatic variants for this specimen: 26 protein-altering or splice-affecting, 10 silent, 45 other (UTR, intronic, flanking, RNA and similar).
By variant classification: 3'UTR 29, Missense Mutation 22, Silent 10, Intron 9, 5'UTR 3, 3'Flank 2, 5'Flank 2, Splice Site 2, Nonsense Mutation 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NRAS | c.183A>T p.Q61H | Missense Mutation (SNP) | VAF 110/167 reads (66%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.316); catalogued as rs121913255, COSV54736320, COSV54736991, COSV54744813; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- CACNA1A | c.127G>A p.G43R | Missense Mutation (SNP) | VAF 174/258 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs763931319; called by muse, mutect2, varscan2
- CARMIL1 | c.2717G>A p.R906H | Missense Mutation (SNP) | VAF 73/166 reads (44%) | SIFT tolerated (0.06); PolyPhen benign (0.444); catalogued as rs1260860195, COSV61515627; called by muse, mutect2, varscan2
- DRD1 | c.473C>A p.P158Q | Missense Mutation (SNP) | VAF 54/108 reads (50%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1184464458; called by muse, mutect2, varscan2
- FBXL17 | c.2084A>G p.N695S | Missense Mutation (SNP) | VAF 71/147 reads (48%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.025); catalogued as COSV62861254; called by muse, mutect2, varscan2
- FSTL5 | c.2470C>T p.R824* | Nonsense Mutation (SNP) | VAF 56/113 reads (50%) | catalogued as rs776031059, COSV60209083; called by muse, mutect2, varscan2
- IGHV2-70 | c.124A>G p.T42A | Missense Mutation (SNP) | VAF 29/30 reads (97%) | SIFT tolerated (0.43); PolyPhen possibly damaging (0.453); catalogued as rs373474286; called by muse, varscan2
- IGHV3-49 | c.37A>C p.I13L | Missense Mutation (SNP) | VAF 82/82 reads (100%) | SIFT tolerated, low confidence (0.69); PolyPhen benign (0.001); catalogued as rs557731208; called by muse, varscan2
- IGLL5 | c.206+2T>G p.X69_splice | Splice Site (SNP) | VAF 8/18 reads (44%) | catalogued as rs561122720, COSV73250168, COSV73251186; called by muse, mutect2
- IGLV3-1 | c.200A>G p.Y67C | Missense Mutation (SNP) | VAF 61/138 reads (44%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.628); catalogued as rs375057861; called by muse, mutect2, varscan2
- KANK1 | c.1231G>A p.D411N | Missense Mutation (SNP) | VAF 18/126 reads (14%) | SIFT tolerated (0.22); PolyPhen benign (0.003); catalogued as rs900068781; called by muse, mutect2, varscan2
- MEGF6 | c.2285C>T p.P762L | Missense Mutation (SNP) | VAF 58/128 reads (45%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.588); catalogued as rs762307115; called by muse, mutect2
- PLCE1 | c.6064C>G p.P2022A | Missense Mutation (SNP) | VAF 28/55 reads (51%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.833); catalogued as COSV53362255; called by muse, mutect2, varscan2
- PLIN4 | c.3751C>T p.R1251W (on ENST00000301286; = p.R1266W on NM_001367868.2) | Missense Mutation (SNP) | VAF 56/192 reads (29%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.625); catalogued as rs542288285, COSV56681306; called by muse, mutect2, varscan2
- SREBF2 | c.1301C>A p.P434Q | Missense Mutation (SNP) | VAF 51/87 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63331285; called by muse, mutect2, varscan2
- ACKR1 | c.739T>G p.W247G | Missense Mutation (SNP) | VAF 6/96 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2
- ADAMTSL3 | c.1253C>G p.P418R | Missense Mutation (SNP) | VAF 46/185 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ATM | c.7089+1_7089+5del p.X2363_splice | Splice Site (DEL) | VAF 216/314 reads (69%) | called by mutect2, pindel, varscan2
- CPVL | c.401C>T p.T134I | Missense Mutation (SNP) | VAF 139/267 reads (52%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- ELFN1 | c.2351G>C p.R784P | Missense Mutation (SNP) | VAF 92/190 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- HIBADH | c.130T>G p.F44V | Missense Mutation (SNP) | VAF 71/191 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); called by muse, mutect2, varscan2
- IGHV5-51 | c.313C>A p.L105M | Missense Mutation (SNP) | VAF 47/49 reads (96%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PEX5L | c.296C>G p.T99R | Missense Mutation (SNP) | VAF 42/104 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- RAPGEF2 | c.4330A>G p.T1444A | Missense Mutation (SNP) | VAF 28/53 reads (53%) | SIFT tolerated, low confidence (0.97); PolyPhen benign (0); called by muse, mutect2, varscan2
- SIPA1L1 | c.411_425del p.N137_N141del | In Frame Del (DEL) | VAF 86/175 reads (49%) | called by mutect2, pindel, varscan2
- SLITRK3 | c.1797C>A p.H599Q | Missense Mutation (SNP) | VAF 59/124 reads (48%) | SIFT tolerated (0.11); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- AP3B2 | c.1308T>C p.C436= | Silent (SNP) | VAF 43/154 reads (28%) | called by muse, mutect2, varscan2
- BMPR1A | c.879G>A p.A293= | Silent (SNP) | VAF 81/214 reads (38%) | catalogued as rs770203548; ClinVar: likely benign; called by muse, mutect2, varscan2
- DHX15 | c.1873C>T p.L625= | Silent (SNP) | VAF 36/67 reads (54%) | called by muse, mutect2, varscan2
- LTBP4 | c.405A>T p.L135= (on ENST00000308370 / NM_001042544.1; = p.L98= on NM_003573.2) | Silent (SNP) | VAF 76/110 reads (69%) | called by muse, mutect2, varscan2
- OR13C2 | c.345G>T p.L115= | Silent (SNP) | VAF 142/437 reads (32%) | called by muse, mutect2, varscan2
- OR5AR1 | c.735T>C p.L245= | Silent (SNP) | VAF 65/136 reads (48%) | catalogued as rs1430062076; called by muse, mutect2, varscan2
- SLC13A5 | c.858C>T p.G286= | Silent (SNP) | VAF 25/74 reads (34%) | catalogued as rs754297638; called by muse, mutect2, varscan2
- SNX14 | c.1242C>T p.F414= (on ENST00000314673 / NM_001350535.1; = p.F370= on NM_020468.5 and 3 other RefSeq transcripts) | Silent (SNP) | VAF 10/32 reads (31%) | called by muse, mutect2, varscan2
- UBA3 | c.547C>T p.L183= | Silent (SNP) | VAF 54/115 reads (47%) | called by muse, mutect2, varscan2
- VNN3 | c.780G>A p.E260= | Silent (SNP) | VAF 82/192 reads (43%) | catalogued as rs1304715203; called by muse, mutect2, varscan2
- AP001267.5 | c.-799+29605T>G | Intron (SNP) | VAF 14/71 reads (20%) | called by muse, mutect2, varscan2
- AP003548.1 | n.336-487C>A | Intron (SNP) | VAF 108/269 reads (40%) | called by muse, mutect2, varscan2
- ARCN1 | c.*1020T>A | 3'UTR (SNP) | VAF 185/781 reads (24%) | called by muse, mutect2, varscan2
- C10orf143 | c.69+2977C>T | Intron (SNP) | VAF 68/142 reads (48%) | called by muse, mutect2, varscan2
- CACNA1I | c.6027+383T>C | Intron (SNP) | VAF 31/68 reads (46%) | called by muse, mutect2, varscan2
- CALHM5 | c.*4595C>A | 3'UTR (SNP) | VAF 32/97 reads (33%) | called by muse, mutect2, varscan2
- CLTC | c.*1040G>T | 3'UTR (SNP) | VAF 52/105 reads (50%) | called by muse, mutect2, varscan2
- COL12A1 | c.*2010G>A | 3'UTR (SNP) | VAF 30/77 reads (39%) | called by muse, mutect2, varscan2
- CPOX | c.*989C>G | 3'UTR (SNP) | VAF 22/36 reads (61%) | called by muse, mutect2, varscan2
- CYYR1 | c.*299A>G | 3'UTR (SNP) | VAF 22/51 reads (43%) | called by muse, mutect2, varscan2
- FOXF2 | c.*53G>A | 3'UTR (SNP) | VAF 24/55 reads (44%) | called by muse, mutect2, varscan2
- GABRG1 | c.*3507C>T | 3'UTR (SNP) | VAF 17/44 reads (39%) | called by muse, mutect2
- GALNT13 | c.*1145C>A | 3'UTR (SNP) | VAF 23/52 reads (44%) | called by muse, mutect2, varscan2
- GLTPP1 | chr11:18188955 G>A | 5'Flank (SNP) | VAF 79/136 reads (58%) | catalogued as rs939418070; called by muse, mutect2, varscan2
- GPR132 | c.*5A>G | 3'UTR (SNP) | VAF 40/125 reads (32%) | called by muse, mutect2, varscan2
- GRAMD1A | chr19:34996111 G>A | 5'Flank (SNP) | VAF 92/138 reads (67%) | catalogued as rs530320130, COSV100526349; called by muse, varscan2
- HAO1 | c.*577C>A | 3'UTR (SNP) | VAF 22/53 reads (42%) | called by muse, mutect2, varscan2
- HERPUD1 | c.906-99T>G | Intron (SNP) | VAF 12/36 reads (33%) | called by muse, mutect2, varscan2
- KCNK3 | c.*4393C>A | 3'UTR (SNP) | VAF 46/102 reads (45%) | called by muse, mutect2, varscan2
- KHSRP | c.*573T>G | 3'UTR (SNP) | VAF 9/29 reads (31%) | called by muse, mutect2, varscan2
- KRTAP4-8 | c.*460C>A | 3'UTR (SNP) | VAF 25/64 reads (39%) | called by muse, mutect2, varscan2
- MAF | c.-289C>T | 5'UTR (SNP) | VAF 8/18 reads (44%) | called by muse, mutect2, varscan2
- MBTD1 | c.*2283_*2284del | 3'UTR (DEL) | VAF 24/58 reads (41%) | called by mutect2, pindel, varscan2
- MBTPS1 | c.*672C>T | 3'UTR (SNP) | VAF 7/32 reads (22%) | catalogued as rs558793609; called by muse, mutect2, varscan2
- MON1A | c.1670+19G>C | Intron (SNP) | VAF 11/23 reads (48%) | called by muse, mutect2, varscan2
- NCAM2 | c.*1565C>A | 3'UTR (SNP) | VAF 15/44 reads (34%) | called by muse, mutect2, varscan2
- NOX4 | c.*1871C>T | 3'UTR (SNP) | VAF 36/168 reads (21%) | called by muse, mutect2, varscan2
- NUDT15 | c.*66G>A | 3'UTR (SNP) | VAF 24/54 reads (44%) | called by muse, mutect2, varscan2
- NUP155 | c.*88G>A | 3'UTR (SNP) | VAF 9/23 reads (39%) | called by muse, mutect2, varscan2
- PHETA2 | c.*474T>A | 3'UTR (SNP) | VAF 47/117 reads (40%) | called by muse, mutect2, varscan2
- PRMT2 | c.-24T>A | 5'UTR (SNP) | VAF 130/242 reads (54%) | called by muse, mutect2, varscan2
- RAB11FIP3 | c.-350T>C | 5'UTR (SNP) | VAF 40/98 reads (41%) | called by muse, mutect2, varscan2
- RAD23B | c.*1613G>A | 3'UTR (SNP) | VAF 8/13 reads (62%) | catalogued as rs1204590535; called by muse, mutect2, varscan2
- SCAMP2 | c.343+76C>G | Intron (SNP) | VAF 15/31 reads (48%) | called by muse, mutect2, varscan2
- SETD5 | c.1078-73_1078-44del | Intron (DEL) | VAF 21/83 reads (25%) | called by mutect2, pindel
- SGMS2 | chr4:107912611 G>A | 3'Flank (SNP) | VAF 47/92 reads (51%) | called by muse, mutect2, varscan2
- SHF | c.303+75C>T | Intron (SNP) | VAF 33/94 reads (35%) | catalogued as rs772231758; called by muse, mutect2, varscan2
- SLC6A5 | c.*1884T>C | 3'UTR (SNP) | VAF 61/118 reads (52%) | called by muse, mutect2, varscan2
- SOX11 | c.*1845T>G | 3'UTR (SNP) | VAF 88/155 reads (57%) | called by muse, mutect2, varscan2
- SOX6 | chr11:15970484 ins A | 3'Flank (INS) | VAF 20/41 reads (49%) | catalogued as rs1486080668; called by mutect2, varscan2
- TIMP3 | c.*2483C>T | 3'UTR (SNP) | VAF 25/52 reads (48%) | catalogued as rs1455892418; called by muse, mutect2, varscan2
- TRAK2 | c.*1745C>G | 3'UTR (SNP) | VAF 17/34 reads (50%) | called by muse, mutect2, varscan2
- UBE3A | c.*1331T>G | 3'UTR (SNP) | VAF 70/115 reads (61%) | called by muse, mutect2, varscan2
- WFDC3 | c.*113C>A | 3'UTR (SNP) | VAF 44/94 reads (47%) | catalogued as COSV99714685; called by muse, mutect2, varscan2
- ZNF780A | c.*812G>A | 3'UTR (SNP) | VAF 39/148 reads (26%) | called by muse, mutect2, varscan2
